Gene-level copy-number profile of tumor specimen TCGA-QC-AA9N-01A from TCGA case TCGA-QC-AA9N, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 53.1 years (19,395 days).
Specimen TCGA-QC-AA9N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.ab0ceefd-4c0f-46a2-9f51-9dbf0aec6a2f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-QC-AA9N-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/37818e50-1b58-4895-a841-fdabe29da19d

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 61; copy number 1: 678; copy number 2: 19,642; copy number 3: 3,237; copy number 4: 28,643; copy number 5: 1,357; copy number 6: 5,177; copy number 7: 82; copy number 8: 365; copy number 9: 16; copy number 10: 119; copy number 11: 244; copy number 13: 108; copy number 16: 81.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-QC-AA9N-01A-11D-A38Y-01): tumor purity 0.75, ploidy 1.75, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 61 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–132,034, 3 genes (within-gene range 0–4): AC093627.1, AC093627.6, AC093627.22.
- chr7:158,957,497–159,233,377, 5 genes: AC004863.1, LINC00689, VIPR2, AC007269.1, PIP5K1P2.
- chr17:28,905,250–29,567,037, 24 genes (within-gene range 0–4): PHF12, AC024267.4, AC024267.5, PIPOX, SEZ6, AC024619.2, AC024619.1, AC024619.4, MYO18A, TIAF1, AC024619.3, AC005412.1, TWF1P1, CRYBA1, NUFIP2, RPL35AP35, AC068025.2, AC068025.1, RNU4-34P, TAOK1, MIR4523, RNU6-711P, RNU6-1034P, ABHD15.
- chr17:29,566,052–29,573,157, 2 genes: TP53I13, AC104564.3.
- chr17:29,625,938–29,930,276, 1 gene (within-gene range 0–2): SSH2.
- chr17:29,716,279–29,883,109, 7 genes: RPL21P123, AC023389.1, AC023389.2, SNORA70, RPL9P30, AC104982.2, AC104982.1.
- chr17:82,389,210–82,650,657, 18 genes (within-gene range 0–4): OGFOD3, Y_RNA, HEXD, HEXD-IT1, CYBC1, AC132938.6, AC132938.3, NARF, AC132938.5, NARF-AS1, NARF-IT1, FOXK2, AC124283.4, AC124283.3, AC124283.2, AC124283.1, WDR45B, AC124283.5.
- chr17:82,668,233–82,668,307, 1 gene: MIR4525.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 568 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:78,597,239–79,767,998, 5 genes, copy number 9 (within-gene range 7–9): ROBO1, AC055731.1, RN7SL751P, AC117461.1, MIR3923.
- chr13:20,973,036–32,538,885, 244 genes, copy number 11 (broad region; genes not listed).
- chr13:97,168,751–97,394,120, 3 genes, copy number 10 (within-gene range 2–10): LINC00456, MBNL2, AL161430.1.
- chr13:102,002,125–102,263,202, 4 genes, copy number 13: LIPT1P1, RNY1P2, MIR4705, RPL39P29.
- chr13:102,299,790–102,300,272, 1 gene, copy number 13: AL356266.1.
- chr13:102,589,372–103,444,968, 19 genes, copy number 13: LINC00555, AL158063.1, TPP2, METTL21C, CCDC168, LINC00283, AL157769.1, TEX30, POGLUT2, BIVM-ERCC5, BIVM, ERCC5, METTL21EP, AL137246.1, AL137246.2, SLC10A2, AL162717.1, LINC01309, ATP6V1G1P7.
- chr13:104,814,327–110,307,157, 63 genes, copy number 13 (broad region; genes not listed).
- chr16:34,962,970–35,912,516, 81 genes, copy number 16 (broad region; genes not listed).
- chr21:14,485,228–17,660,384, 54 genes, copy number 9–13: SAMSN1, SAMSN1-AS1, AF127936.1, POLR2CP1, GAPDHP16, AF127577.4, LINC02246, RBMX2P1, AF127577.3, NRIP1, AF127577.1, AF127577.2, AF127577.6, AF127577.5, AF222684.1, AF222685.1, AF130248.1, AF246928.1, AJ009632.2, CYCSP42, AJ009632.1, RNU6-1326P, RAD23BP3, USP25, RBPMSLP, MIR99AHG, RNU6-426P, VDAC2P1, RPS26P5, SNORD74B, AP001172.1, AP001172.2, AP000962.3, AP000962.2, MIR99A, MIRLET7C, AP000962.1, MIR125B2, RNU1-98P, AF130359.1, AF212831.1, NEK4P1, AP000457.1, RNU6-113P, LINC01549, RPL39P40, RN7SL163P, CXADR, BTF3L4P1, Y_RNA, Y_RNA, BTG3, BTG3-AS1, AP000432.1.
- chr21:17,901,263–19,345,312, 16 genes, copy number 10 (within-gene range 7–10): CHODL, AF130417.1, TMPRSS15, AL109763.1, MIR548XHG, AF240627.1, MIR548X, PPIAP22, AL157359.3, AL157359.2, AL157359.1, AP000431.2, AP000431.1, SLC6A6P1, AP000855.1, RNU1-139P.
- chr21:20,256,752–22,205,332, 21 genes, copy number 10: LINC02573, RNU6-772P, RN7SKP147, FDPSP6, KRT18P2, RPS3AP1, AP001506.1, LINC00320, PPIAP1, NCAM2, AP001136.1, AP001117.1, AF241725.1, LINC00317, LINC01425, AP000472.1, LINC01687, LINC00308, AP000705.2, AP000705.1, RNU4-45P.
- chr21:23,960,569–24,321,377, 5 genes, copy number 10 (within-gene range 8–10): AP000477.2, AP000477.3, AP000477.1, AP000470.1, LINC01689.
- chr21:25,169,431–25,607,517, 10 genes, copy number 10 (within-gene range 8–10): AP001341.1, RNA5SP489, RPL13AP7, AP001340.1, LINC00158, AP000221.1, MIR155HG, MIR155, AP000223.1, MRPL39.
- chr21:26,393,635–29,288,205, 39 genes, copy number 10 (within-gene range 8–10): CYYR1-AS1, AP001596.2, CYYR1, ADAMTS1, AP001599.1, ADAMTS5, MIR4759, GPX1P2, AP001605.1, AP001604.1, EIF4A1P1, RPL10P1, NCSTNP1, LINC01673, LINC00113, AJ006995.1, LINC00314, LINC01697, LINC01695, AF165147.1, LINC00161, U6, N6AMT1, HSPD1P7, THUMPD1P1, LTN1, RPL23P2, RWDD2B, AF129075.2, USP16, CCT8, AF129075.1, AF129075.3, MAP3K7CL, RPL12P9, Y_RNA, U3, AF124730.1, LINC00189.
- chr21:29,222,321–29,361,894, 3 genes, copy number 10: GAPDHP14, BACH1-IT1, AP000240.1.

Autosomal genes at a single copy (total copy number 1): 678. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
